Somatic mutation profile of tumor specimen TARGET-10-PARSGM-09A (aliquot TARGET-10-PARSGM-09A-01D) from TARGET case TARGET-10-PARSGM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.3 years (4,849 days).
Specimen TARGET-10-PARSGM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f960ada-7d06-4acf-b90e-fa1ec8936984.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARSGM-10A (Blood Derived Normal), aliquot TARGET-10-PARSGM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce2a3bac-71ca-42a2-81f1-d5dae09a8bc4

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 3'UTR 1, Silent 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 31/59 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGFG2 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs866159410; called by muse, mutect2, varscan2
- CELF4 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as rs753645312, COSV58450779; called by muse, mutect2, varscan2
- SEMA3C | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772127699; called by muse, mutect2, varscan2
- GFAP | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- GPR174 | c.107_109dup p.G36_N37insR | In Frame Ins (INS) | VAF 23/197 reads (12%) | called by mutect2, pindel, varscan2
- ZNF536 | c.954C>T p.H318= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV100835231; called by muse, mutect2, varscan2
- SLC12A6 | c.*96dup | 3'UTR (INS) | VAF 27/73 reads (37%) | called by mutect2, pindel, varscan2
- TIMM50 | c.291+87G>A | Intron (SNP) | VAF 34/59 reads (58%) | catalogued as rs777434495; called by muse, mutect2, varscan2
